CCDI case PBCHMT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/814c8521-8a56-4b38-83fc-de4dc95a0d79

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 1.9 years (702 days).

Biospecimens (3 samples)
- Sample 0DSEYU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZ7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEZO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
